Somatic mutation profile of tumor specimen 0DRZIW from CCDI case PBCHGB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.1 years (4,426 days).
Specimen 0DRZIW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30e9105b-7338-458d-acc5-0940edd201b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRZJG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03f59e59-f454-463d-a9a3-2d277df88fba

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIPK1 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 262/907 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs750830587, COSV52528025; called by muse, mutect2, varscan2
- SRBD1 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 252/918 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.806); catalogued as rs1474857890; called by muse, mutect2, varscan2
- DSC1 | c.2483G>A p.G828D | Missense Mutation (SNP) | VAF 240/504 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF3C | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 442/1943 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MTTP | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 150/993 reads (15%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC12 | c.3737C>T p.T1246I (on ENST00000379442; = p.T1103I on NM_001164462.1) | Missense Mutation (SNP) | VAF 67/1254 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- SH2D5 | c.608C>T p.A203V (on ENST00000444387 / NM_001103161.2; = p.A119V on NM_001103160.2) | Missense Mutation (SNP) | VAF 52/877 reads (6%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.99); called by muse, mutect2
- PCNX1 | c.2400G>A p.G800= | Silent (SNP) | VAF 121/421 reads (29%) | called by muse, mutect2, varscan2
- C16orf91 | c.32+11C>T | Intron (SNP) | VAF 94/442 reads (21%) | catalogued as rs1429433005; called by muse, mutect2, varscan2
